CCDI case PBCBSV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/725e638e-6263-49f5-8c41-9f1c3b9291eb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Paraganglioma, malignant: ICD-O-3 morphology code: 8680/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.7 years (2,435 days).

Biospecimens (3 samples)
- Samples 0DR0C2, 0DR0DI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR0CB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
